EXCEPTIONAL_RESPONDERS case ER-AC3P — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c5058c69-b7d4-4e69-b1b2-d11872d8abd7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Dead; Days to death: 4,552 days (12.5 years); Year of death: 2016.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 60.6 years (22,151 days); Year of diagnosis: 2004; AJCC clinical stage: Stage IVA; Prior malignancy: no; Days to last follow up: 4,026 days (11.0 years); Days to best overall response: 247 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Cisplatin + Docetaxel + Fluorouracil; Days to treatment start: 14 days; Days to treatment end: 125 days.

Follow-up (1 entry)
- Days to follow up: 4,026 days (11.0 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 4,026 days (11.0 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AC3P-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-AC3P-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 40; Percent normal cells: 45; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
